Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A8E3, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A8E3-01A (Primary Tumor).

ICD-O-3
Adenocarcinoma NOS 8140/3
Site: Gastric antrum C16.3
JW 11/23/13

Collect date:

(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Antrum)

1 - "Body and antrum of the stomach":

-Poorly differentiated adenocarcinoma (intestinal pattern of Laurén) ulcerated, infiltrating the subserosal adipose tissue;

-Greatest dimension of tumor: 7.5 cm;

-Angiolymphatic invasion: present;

-Perineural invasion: not detected;

-Adjacent mucosa: low-grade epithelial dysplasia and intestinal metaplasia;

-Surgical margins: uninvolved by neoplasia.

-Omentum: absence of neoplasia.

Lymph nodes of lesser curvature: absence of neoplasia (0/10).

Lymph nodes of greater curvature: absence of neoplasia (0/6).

2 - "Number 6 lymph node":

Fibrous connective tissue and adipose tissue uninvolved by neoplasia.

3 - "Peripancreatic lymph node":

Fibrous connective tissue and adipose tissue uninvolved by neoplasia.

4 - "Anterior layer of the transverse mesocolon":

Absence of neoplasia.

5 - "8P lymph node":

Uninvolved by neoplasia (0/4).

6 - "11P lymph node":

Fibrous connective tissue and adipose tissue uninvolved by neoplasia.

7 - "Gallbladder":

Uninvolved by neoplasia.

ICD-O Discrepancy		☒
Prior Malignancy / History		☒

Source: NCI Genomic Data Commons file ddbd487c-d56a-430c-a0e0-c2bd7232984e (TCGA-VQ-A8E3.6A34D385-D1BB-428E-A41E-7DC3C0836741.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).